Somatic mutation profile of tumor specimen TCGA-EA-A411-01A (aliquot TCGA-EA-A411-01A-11D-A243-09) from TCGA case TCGA-EA-A411, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 50.8 years (18,561 days).
Specimen TCGA-EA-A411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8492fc-02d7-4b22-bb8f-b57243a3cb2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A411-10A (Blood Derived Normal), aliquot TCGA-EA-A411-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95de4e1c-e05c-4970-b50f-86f694ccd376

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 12, Nonsense Mutation 3, Splice Site 2, RNA 2, In Frame Ins 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV57246601, COSV57252959; called by muse, varscan2
- ABCD1 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM105298, COSV54384650; called by muse, varscan2
- AFM | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as COSV56920073; called by muse, mutect2, varscan2
- AFMID | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs575961186, COSV59976060; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1118A>G p.Q373R | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV62005020; called by muse, mutect2, varscan2
- BICD2 | c.2407C>G p.H803D | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as COSV63548949; called by muse, mutect2, varscan2
- C1QC | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1373636175, COSV65889544; called by muse, mutect2, varscan2
- CEP128 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as COSV55376034; called by muse, mutect2, varscan2
- CIAO3 | c.146A>T p.Y49F | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.274); catalogued as COSV52402161; called by muse, mutect2, varscan2
- CIT | c.5630C>A p.A1877D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99950804; called by muse, mutect2
- DHRS3 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV66108215; called by muse, mutect2, varscan2
- DPY19L4 | c.1556C>A p.T519N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.242); catalogued as COSV68962852; called by muse, mutect2, varscan2
- EPHA10 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.731); catalogued as rs770820031, COSV60402948; called by muse, mutect2, varscan2
- EPHA7 | c.1121G>T p.W374L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV65182367; called by muse, mutect2, varscan2
- FLRT2 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs754917817, COSV58139180; called by muse, mutect2, varscan2
- FOLH1 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57048884; called by muse, mutect2, varscan2
- HDC | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as rs749851294, COSV51068330; called by muse, mutect2, varscan2
- IGHV2-70 | c.96A>T p.K32N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368957766; called by muse, mutect2, varscan2
- IL1RAPL2 | c.809G>T p.G270V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61149689, COSV61156368; called by muse, mutect2, varscan2
- JAKMIP3 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53823043; called by muse, mutect2, varscan2
- KATNBL1 | c.788+1G>T p.X263_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV56623268; called by muse, mutect2, varscan2
- LYPLAL1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.166); catalogued as COSV65106608; called by muse, mutect2, varscan2
- NDUFA9 | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.049); catalogued as COSV56929096; called by muse, mutect2, varscan2
- NOD1 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV56112395; called by muse, mutect2, varscan2
- NRP1 | c.1400G>C p.S467T | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as COSV55166390; called by muse, mutect2, varscan2
- OXSR1 | c.214C>G p.H72D | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61258618; called by muse, mutect2, varscan2
- PABPC5 | c.1052T>C p.F351S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV57040624; called by muse, mutect2, varscan2
- PAK5 | c.1190C>T p.T397M | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1018346655, COSV62026383, COSV62026965; called by muse, mutect2, varscan2
- PDIA5 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs774726526, COSV60249034; called by muse, mutect2, varscan2
- POLR2J3 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 56/706 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs1273031613; called by muse, mutect2
- SAMD1 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV54115364; called by muse, mutect2, varscan2
- SLC5A2 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57891440, COSV57892633; called by muse, mutect2, varscan2
- SMCHD1 | c.2848C>T p.Q950* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV55257132; called by muse, mutect2, varscan2
- TANGO6 | c.2966A>G p.D989G | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs1220296056; called by muse, mutect2, varscan2
- TDRD6 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs781647844, COSV60175543; called by muse, mutect2, varscan2
- TLK1 | c.817A>C p.M273L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as COSV62630173; called by muse, mutect2, varscan2
- TSPAN7 | c.441+1G>A p.X147_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as rs111443672, COSV54530621; called by muse, mutect2, varscan2
- USP51 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as COSV72351629, COSV72351917; called by muse, mutect2, varscan2
- WRAP53 | c.696T>A p.Y232* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV56833460; called by muse, mutect2, varscan2
- ZMAT1 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV65658496; called by muse, mutect2, varscan2
- ZNF419 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.846); catalogued as COSV55659660; called by muse, mutect2, varscan2
- LTB4R | c.325_326insGTG p.T109delinsSA | In Frame Ins (INS) | VAF 2/13 reads (15%) | called by muse*, mutect2
- MAGEB6B | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC12A5 | c.2412_2420del p.Q804_D807delinsH (on ENST00000454036 / NM_001134771.2; = p.Q781_D784delinsH on NM_020708.5) | In Frame Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- ARHGEF12 | c.360T>G p.T120= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs752513752, COSV63104524; called by muse, mutect2, varscan2
- ARHGEF2 | c.846C>T p.C282= (on ENST00000361247 / NM_001162383.2; = p.C254= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs761662798, COSV100561131; called by muse, mutect2, varscan2
- ASL | c.90C>T p.Y30= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs751062108, COSV59188414; ClinVar: likely benign; called by muse, mutect2, varscan2
- GPR45 | c.153C>A p.G51= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV51523860; called by muse, mutect2, varscan2
- L3MBTL3 | c.1114C>A p.R372= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV62386111, COSV62387551; called by muse, mutect2, varscan2
- PALM | c.489C>T p.P163= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV52768080; called by muse, mutect2, varscan2
- PCDHGB4 | c.1902C>T p.D634= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs368188508; called by muse, mutect2, varscan2
- SPAST | c.726T>C p.T242= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV59514366; called by muse, mutect2, varscan2
- SRGAP1 | c.861G>A p.A287= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs137909926; called by muse, mutect2, varscan2
- SRPX2 | c.777A>G p.V259= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs775755373, COSV65933570; called by muse, mutect2, varscan2
- VNN3 | c.729C>T p.C243= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as COSV51590818; called by muse, mutect2, varscan2
- VPS13B | c.9486T>G p.P3162= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV62141146; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73826549 C>A | 3'Flank (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- CDC37P1 | n.305A>G | RNA (SNP) | VAF 9/41 reads (22%) | catalogued as rs757379507; called by mutect2, varscan2
- CDC37P1 | n.304G>T | RNA (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
